TCGA case TCGA-10-0938 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: MD Anderson Cancer Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/7ca97692-0bf5-4bbd-81ce-10a051d04bd5

Demographics
Sex at birth: female; Race: white; Age at index: 80 years; Vital status: Dead; Days to death: 636 days (1.7 years).

Diagnoses (2)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 80.9 years (29,558 days); Year of diagnosis: 2002; FIGO stage: Stage IIIC; Tumor grade: G3; Prior treatment: No.
   Pathology details: Residual tumor measurement: >20 mm.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Letrozole; Treatment intent type: Adjuvant; Initial disease status: Progressive Disease; Days to treatment start: 30 days; Days to treatment end: 148 days; Treatment dose: 225 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Leuprolide Acetate; Treatment intent type: Adjuvant; Initial disease status: Progressive Disease; Days to treatment start: 30 days; Days to treatment end: 153 days; Treatment dose: 4 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Initial disease status: Progressive Disease; Days to treatment start: 41 days; Days to treatment end: 188 days; Number of cycles: 6; Treatment dose: 3,150 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Docetaxel; Treatment intent type: Adjuvant; Initial disease status: Progressive Disease; Days to treatment start: 41 days; Days to treatment end: 188 days; Number of cycles: 6; Treatment dose: 960 mg/m2; Route of administration: Intravenous.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Metastasis of diagnosis 1 (Serous cystadenocarcinoma, NOS). Age at diagnosis: 81.9 years (29,920 days); Days to diagnosis: 362 days; Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 362 days.

Follow-up (5 entries)
- Day 362 (post initial treatment): Progression or recurrence: Yes; Days to progression: 362 days; Evidence of progression type: Convincing Image Source.
- Days to follow up: 604 days (1.7 years); Disease response: With Tumor.
- Days to follow up: 636 days (1.7 years); Disease response: With Tumor.
- ECOG performance status: 2.
- Progression or recurrence: Yes; Progression or recurrence type: Distant; Evidence of progression type: Convincing Image Source; Timepoint: Post Initial Treatment.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-10-0938-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1; Intermediate dimension: 0.6; Shortest dimension: 0.6.
  Slide TCGA-10-0938-01A-01-BS1: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 85; Percent normal cells: 10; Percent necrosis: 0; Percent stromal cells: 20.
  Slide TCGA-10-0938-01A-02-BS2: Section location: Bottom; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 5; Percent necrosis: 0; Percent stromal cells: 15.
- Sample TCGA-10-0938-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: With tumor; History neoadjuvant treatment: No.
- Drug treatment 1: Pharmaceutical therapy drug name: Lupron; Therapy regimen: OTHER, SPECIFY IN NOTES; Therapy regimen other: Adjuvant and Progression.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 3: Pharmaceutical therapy drug name: Taxotere; Therapy regimen: OTHER, SPECIFY IN NOTES; Therapy regimen other: Adjuvant and Progression.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 636 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 636 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 362 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-10-0938-01): tumor purity 0.96, ploidy 3.84, whole-genome doublings 2 (call status: legacy_call).
